CCDI case PBCVLY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/551fca70-2bef-46f1-a2ea-6a0911005eab

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E0THA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E0THI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E0THQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
